TCGA case TCGA-49-4501 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0780eb43-d5b5-4c3d-9825-beacba5cc723

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 1,421 days (3.9 years).

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.9 years (24,817 days); Year of diagnosis: 1996; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 664 days (1.8 years); Days to treatment end: 694 days (1.9 years); Number of cycles: 2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Malignant lymphoma, NOS: ICD-O-3 morphology code: 9590/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 69.4 years (25,362 days); Days to diagnosis: 545 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 545 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,421 days (3.9 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-49-4501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-49-4501-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-49-4501-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-49-4501-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-49-4501-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Upper.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Recurrence.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Treatment outcome at TCGA followup: Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Lymph Node(s) Cervical; Other malignancy histological type: Lymphoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy lymphoma. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,421 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,421 days; disease-free interval: event (new tumor event after initially disease-free), 545 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 545 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-49-4501-01A-01D-1204-01): tumor purity 0.43, ploidy 2.72, whole-genome doublings 1.
